Somatic mutation profile of tumor specimen TCGA-AJ-A3BH-01A (aliquot TCGA-AJ-A3BH-01A-11D-A19Y-09) from TCGA case TCGA-AJ-A3BH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3.
Specimen TCGA-AJ-A3BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf6ae935-081c-4df5-a9e2-f44c5780a906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3BH-10A (Blood Derived Normal), aliquot TCGA-AJ-A3BH-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a57188b9-42fa-4db6-8e32-bb0bf1c23756

The open-access MAF lists 3,214 somatic variants for this specimen: 2,410 protein-altering or splice-affecting, 731 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,907, Silent 731, Frame Shift Del 286, Nonsense Mutation 99, Frame Shift Ins 41, Splice Site 35, Intron 29, Splice Region 22, RNA 20, In Frame Del 17, 3'UTR 9, 3'Flank 9.

Variants (750 of 3,214; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- CASP8 | c.742C>T p.R248W (on ENST00000432109 / NM_033355.3; = p.R265W on NM_001228.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs17860424, CM023571, COSV51855342; ClinVar: pathogenic; called by muse, varscan2
- CEP290 | c.1666del p.I556Ffs*17 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs727503855, CD073590; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CHD8 | c.2626C>T p.R876* (on ENST00000646647 / NM_001170629.2; = p.R597* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs1555315679, COSV101303044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.2110C>T p.R704* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as rs151340624, CM960314, COSV100259808; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CYP1B1 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs56010818, CM980503, COSV99307249; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DCX | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs104894784, CM980522, CM990468, COSV57572908; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF1AX | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV63309390, COSV63309515; called by muse, mutect2, varscan2
- ERBB2 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen possibly damaging (0.599); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EVC | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs1446547358, COSV53835266; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1321C>T p.R441W (on ENST00000281708 / NM_001349798.2; = p.R361W on NM_018315.5) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55897212, COSV55936558; called by muse, mutect2, varscan2
- FGFR1 | c.1019C>T p.T340M (on ENST00000447712 / NM_023110.3; = p.T338M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1064793123, CM0911318, COSV58331507; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H1-2 | c.67_69del p.K23del | In Frame Del (DEL) | VAF 20/63 reads (32%) | hotspot (GDC flag); catalogued as rs751086925; called by pindel, varscan2
- HPS1 | c.962del p.G321Afs*10 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs281865081, CD982690; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HUWE1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520538, CM152728, COSV53364621; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- LAMA1 | c.7180C>T p.R2394* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as rs542213899, COSV101055124; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 42/70 reads (60%) | catalogued as rs61749721, CM992179, COSV100317851; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28929483, CM930498, COSV51877870, COSV99253264; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MYL2 | c.431del p.P144Lfs*3 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs786205430, CD130651; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by mutect2, pindel
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PDHA1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863224148, CM920568, COSV63327821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2
- RASA1 | c.2707C>T p.R903* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as rs1554050230, CM1311713, COSV57192847; ClinVar: pathogenic; called by muse, varscan2
- RP1 | c.3843del p.P1282Lfs*12 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs769601671; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN5A | c.3694C>T p.R1232W (on ENST00000333535 / NM_198056.3; = p.R1231W on NM_000335.5) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs199473207, CM983679, COSV100346639, COSV61120841; ClinVar: uncertain significance / not provided / pathogenic; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- WDR19 | c.641del p.L214* | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs587777348; ClinVar: pathogenic; called by mutect2, varscan2
- ZBTB18 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1553270634, COSV62396575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs370481312; called by muse, mutect2, varscan2
- AASDH | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV99220841; called by muse, mutect2, varscan2
- ABCA12 | c.6392C>T p.P2131L (on ENST00000272895 / NM_173076.3; = p.P1813L on NM_015657.3) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs758142404, COSV99788485; called by muse, mutect2, varscan2
- ABCA12 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs768133744, COSV55981680, COSV99789541; called by muse, mutect2, varscan2
- ABCA8 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99284901; called by muse, mutect2, varscan2
- ABCA9 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs773108471; called by muse, mutect2
- ABCB8 | c.1815C>T p.V605= (on ENST00000297504 / NM_001282291.2; = p.V588= on NM_007188.5) | Splice Region (SNP) | VAF 9/26 reads (35%) | catalogued as rs767120059, COSV99873872; called by muse, mutect2, varscan2
- ABCB8 | c.1826del p.G609Afs*25 (on ENST00000297504 / NM_001282291.2; = p.G592Afs*25 on NM_007188.5) | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as COSV99875127; called by mutect2, pindel, varscan2
- ABCC1 | c.2911G>A p.G971R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1198050880, COSV60693454; called by muse, mutect2, varscan2
- ABCC10 | c.1511C>T p.A504V (on ENST00000372530 / NM_001198934.2; = p.A461V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543886430, COSV55084501; called by mutect2, varscan2
- ABCC11 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1374115070, COSV100750547; called by mutect2, varscan2
- ABCC2 | c.2249A>G p.D750G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100966401; called by muse, mutect2, varscan2
- ABCC2 | c.2902C>A p.L968M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV100966402; called by muse, mutect2, varscan2
- ABCC3 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1003354, COSV99558717; called by muse, mutect2, varscan2
- ABCC6 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228104; called by muse, mutect2, varscan2
- ABCD2 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429172; called by muse, mutect2
- ABHD13 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV101024049; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781344834, COSV101352244; called by muse, mutect2, varscan2
- ABL1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs1318764515, COSV100583478; called by muse, mutect2
- ABL1 | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV59336112; called by muse, mutect2, varscan2
- AC004922.1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.53); catalogued as rs1428599750, COSV99500954; called by muse, mutect2, varscan2
- AC006059.2 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs564647857, COSV100045189; called by muse, mutect2, varscan2
- AC126283.2 | c.111del p.K37Nfs*65 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs1560546604; called by mutect2, pindel, varscan2
- ACACB | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100622366; called by muse, mutect2, varscan2
- ACADL | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99284542; called by muse, mutect2, varscan2
- ACADS | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99656624; called by muse, mutect2, varscan2
- ACADVL | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs398123086, COSV99138331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAP2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229683210, COSV100461499, COSV58749569; called by mutect2, varscan2
- ACE | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99328543; called by muse, mutect2, varscan2
- ACE | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746397573, COSV52003879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACE2 | c.2278C>A p.L760M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99382562; called by mutect2, varscan2
- ACKR3 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs764138712, COSV56021529; called by muse, mutect2, varscan2
- ACOT11 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs748574584, COSV59347296; called by muse, mutect2, varscan2
- ACOT11 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs778640519, COSV100650489; called by muse, mutect2, varscan2
- ACOT8 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747087835, COSV54168584; called by muse, mutect2, varscan2
- ACSL6 | c.1415C>A p.P472H (on ENST00000379240; = p.P497H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99732741; called by muse, mutect2, varscan2
- ACTG2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs753251409, COSV100608871, COSV61828300; called by muse, mutect2, varscan2
- ACTL7B | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV101012494; called by muse, mutect2, varscan2
- ACTL8 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1182735417, COSV64862601; called by muse, mutect2, varscan2
- ACTN3 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763136343, COSV72207580; called by muse, mutect2, varscan2
- ACTR1A | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760845113, COSV64024527; called by muse, varscan2
- ACTRT1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs373832447, COSV64419671; called by muse, mutect2, varscan2
- ACVRL1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746197083, COSV66359467, COSV66361012; called by muse, mutect2, varscan2
- ADAM17 | c.843G>A p.Q281= | Splice Region (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100176049; called by muse, mutect2, varscan2
- ADAM19 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as rs199516624, COSV57434609; called by muse, mutect2, varscan2
- ADAM28 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as COSV99737833; called by muse, mutect2, varscan2
- ADAM7 | c.2045G>A p.G682D | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as COSV99443054; called by muse, mutect2, varscan2
- ADAMTS14 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV100941386; called by muse, mutect2, varscan2
- ADAMTS3 | c.1585T>C p.C529R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99710284; called by muse, mutect2, varscan2
- ADAMTS7 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769188745, COSV101183017; called by muse, mutect2, varscan2
- ADAMTS9 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV99898782; called by muse, mutect2, varscan2
- ADAMTSL1 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1407832761, COSV52816530; called by muse, mutect2
- ADARB1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62344838; called by muse, mutect2, varscan2
- ADCK5 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs782038841, COSV58235649; called by muse, mutect2
- ADCK5 | c.1573G>A p.G525S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs781929458, COSV100450215; called by muse, mutect2
- ADCY2 | c.1816T>C p.C606R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100601858; called by muse, mutect2, varscan2
- ADCY6 | c.3257-2A>G p.X1086_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as rs1390066140, COSV100326414; called by muse, mutect2, varscan2
- ADCY7 | c.378G>T p.V126= | Splice Region (SNP) | VAF 4/64 reads (6%) | catalogued as rs1022638294; called by muse, mutect2
- ADCYAP1 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV52486391; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRE5 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs372889912; called by muse, mutect2, varscan2
- ADGRG4 | c.7417G>T p.E2473* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99794448; called by muse, mutect2, varscan2
- ADGRG5 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs561596941, COSV100446337; called by muse, mutect2, varscan2
- ADGRG6 | c.2524C>T p.H842Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745898; called by muse, mutect2, varscan2
- ADGRV1 | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as rs200389929, COSV67983288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADHFE1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as rs148191690; called by muse, mutect2, varscan2
- ADK | c.128A>C p.D43A (on ENST00000286621; = p.D26A on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV99691653; called by muse, mutect2, varscan2
- ADPGK | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs761019721, COSV100295148; called by muse, mutect2, varscan2
- ADRM1 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs373828612, COSV53368060; called by muse, mutect2, varscan2
- AEBP1 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs150909656; called by muse, mutect2, varscan2
- AFF2 | c.2608C>T p.R870C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782135667, COSV99662037; called by muse, mutect2, varscan2
- AGAP2 | c.1610C>T p.A537V (on ENST00000547588 / NM_001122772.2; = p.A201V on NM_014770.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs374453424; called by muse, mutect2, varscan2
- AGAP3 | c.757C>T p.R253* (on ENST00000622464; = p.R289* on NM_031946.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV58994596; called by muse, mutect2, varscan2
- AGBL1 | c.2158C>A p.P720T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV101222271; called by muse, mutect2, varscan2
- AGO4 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs1351551601, COSV100942774, COSV64617953; called by muse, mutect2, varscan2
- AGT | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as rs1253843593, COSV100794212; called by muse, mutect2, varscan2
- AHNAK | c.8890C>A p.P2964T | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57221923, COSV99945709; called by muse, mutect2, varscan2
- AHNAK2 | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs368303682, COSV60909948, COSV60923711; called by muse, mutect2, varscan2
- AK3 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750035551, COSV100729388; called by muse, mutect2, varscan2
- AKAP6 | c.3082G>A p.V1028I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs141386857, COSV55214164; called by muse, mutect2, varscan2
- AKAP9 | c.11350A>G p.K3784E (on ENST00000359028; = p.K3760E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV100661937; called by muse, mutect2, varscan2
- AKR1B10 | c.336G>A p.W112* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs1161467816, COSV100610126; called by muse, mutect2, varscan2
- AL136295.1 | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99937778; called by muse, mutect2, varscan2
- AL136295.1 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs942417338, COSV99937780; called by muse, mutect2, varscan2
- AL713999.2 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99825869; called by muse, mutect2, varscan2
- ALDH18A1 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs1283928441, COSV64662095; ClinVar: uncertain significance; called by muse, mutect2
- ALDH1A3 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1188366940, COSV100320252; called by muse, mutect2, varscan2
- ALDH3B1 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs533370288, COSV99141691; called by muse, mutect2, varscan2
- ALK | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1469128263, COSV101201338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH6 | c.133G>A p.A45T (on ENST00000252984 / NM_001297701.2; = p.A73T on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as COSV99430850; called by muse, varscan2
- ALLC | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV99377543; called by muse, mutect2, varscan2
- ALOX15 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs1372161005, COSV99541180; called by muse, mutect2, varscan2
- ALOX15 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV53401315; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALPK3 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766905744, COSV51937501; called by muse, mutect2, varscan2
- ALPP | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101235089; called by muse, mutect2, varscan2
- ALX3 | c.500A>C p.E167A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100873867; called by muse, mutect2, varscan2
- AMER3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs766270630, COSV58465000; called by muse, mutect2, varscan2
- AMPD3 | c.515G>A p.R172H (on ENST00000396553 / NM_001025389.2; = p.R181H on NM_000480.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs754636700, COSV101158088, COSV67329860; called by muse, mutect2, varscan2
- AMZ2 | c.724A>T p.S242C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100703102; called by muse, mutect2, varscan2
- ANGPT1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs568159633, COSV52456443; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANK3 | c.8464C>T p.P2822S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV55049158, COSV99778451; called by muse, mutect2, varscan2
- ANKEF1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101000984; called by muse, mutect2, varscan2
- ANKHD1 | c.7589C>T p.A2530V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs1422823941, COSV99782154; called by muse, mutect2, varscan2
- ANKIB1 | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99728395; called by muse, mutect2, varscan2
- ANKK1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV100392710; called by muse, mutect2, varscan2
- ANKRD17 | c.2923G>A p.A975T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs770988706, COSV100428597; called by muse, mutect2, varscan2
- ANKRD2 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); catalogued as COSV100080716; called by muse, mutect2, varscan2
- ANKRD2 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100080719; called by muse, mutect2
- ANKRD30A | c.697G>A p.A233T (on ENST00000611781; = p.A177T on NM_052997.2) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.945); catalogued as COSV100652972; called by muse, mutect2, varscan2
- ANKRD30A | c.2672C>T p.P891L (on ENST00000611781; = p.P835L on NM_052997.2) | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.927); catalogued as rs1475783959, COSV64622466; called by muse, mutect2, varscan2
- ANKRD30A | c.3679G>C p.G1227R (on ENST00000611781; = p.G1171R on NM_052997.2) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100652976; called by muse, mutect2, varscan2
- ANKS3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754447725, COSV100172793; called by muse, mutect2, varscan2
- ANO2 | c.2705G>A p.R902H (on ENST00000356134 / NM_001278597.3; = p.R906H on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192113570, COSV59020943; called by muse, mutect2
- ANO2 | c.1381C>T p.R461* (on ENST00000356134 / NM_001278597.3; = p.R465* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs201292658; called by muse, mutect2, varscan2
- ANO5 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1417289245, COSV100201433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO6 | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100262394; called by muse, mutect2, varscan2
- ANO8 | c.2474G>A p.G825D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344080; called by muse, mutect2, varscan2
- ANO9 | c.1794G>A p.W598* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100229816; called by muse, mutect2
- ANOS1 | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.34); catalogued as rs1569252011, COSV99390469, COSV99390787; called by muse, mutect2
- ANPEP | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs373138765; called by muse, mutect2, varscan2
- ANXA2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs138727673; called by muse, mutect2, varscan2
- AOX1 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs752882911, COSV65981708; called by muse, mutect2, varscan2
- AP1G1 | c.1804A>G p.N602D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100250063; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs753029866; called by mutect2, varscan2
- AP3D1 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); catalogued as rs769520832, COSV100642402; called by muse, mutect2, varscan2
- APBA3 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs967318496, COSV99515775; called by muse, mutect2
- APBB3 | c.1132G>A p.A378T (on ENST00000357560 / NM_133173.2; = p.A385T on NM_006051.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs777567525, COSV100021159; called by muse, mutect2, varscan2
- APCDD1L | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64487025; called by muse, mutect2, varscan2
- APLP1 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV99383607; called by muse, mutect2, varscan2
- APOB | c.13054C>A p.L4352I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as COSV99263788; called by mutect2, varscan2
- APOL1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs753380461, COSV59869114; called by muse, mutect2, varscan2
- AQP12A | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs766634316, COSV61837311; called by mutect2, varscan2
- AQP12B | c.352C>T p.R118C (on ENST00000621682; = p.R130C on NM_001102467.2) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs372967359; called by muse, mutect2, varscan2
- AQP3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs762587298, COSV53048738; called by muse, mutect2, varscan2
- AQR | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs573016803, COSV50030242; called by muse, mutect2, varscan2
- AR | c.1768G>T p.G590W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101017463; called by muse, mutect2, varscan2
- ARAP1 | c.2321G>A p.C774Y (on ENST00000393609 / NM_001040118.2; = p.C529Y on NM_015242.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100501577; called by muse, mutect2
- ARAP3 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99499344; called by muse, mutect2, varscan2
- ARAP3 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778849352, COSV99499346, COSV99500054; called by muse, mutect2, varscan2
- ARF3 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.042); catalogued as rs1246000356, COSV99873021; called by muse, mutect2, varscan2
- ARFGEF2 | c.2282C>T p.T761I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.821); catalogued as COSV100903997; called by muse, mutect2, varscan2
- ARFGEF2 | c.4975C>A p.L1659M | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV64216596; called by muse, mutect2, varscan2
- ARHGAP20 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs746235944, COSV52806977; called by muse, mutect2, varscan2
- ARHGAP21 | c.3341C>T p.T1114I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs746946721, COSV100255806, COSV57611346; called by muse, mutect2, varscan2
- ARHGAP21 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs766681197, COSV100255808; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP4 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs782262781, COSV61685783; called by muse, mutect2, varscan2
- ARHGAP5 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs746935718, COSV100565027; called by muse, mutect2, varscan2
- ARHGEF1 | c.1830G>T p.E610D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV100528879; called by muse, mutect2
- ARHGEF15 | c.1949del p.G650Afs*145 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as COSV62725865; called by mutect2, pindel
- ARHGEF17 | c.1925G>T p.S642I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as COSV99734935; called by muse, mutect2
- ARHGEF2 | c.1804C>T p.R602W (on ENST00000361247 / NM_001162383.2; = p.R574W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs925121851, COSV100560072; called by muse, mutect2, varscan2
- ARHGEF26 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100726393; called by muse, mutect2, varscan2
- ARHGEF28 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as COSV99708222; called by muse, mutect2, varscan2
- ARHGEF39 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs775025214, COSV58397623; called by muse, mutect2, varscan2
- ARID1A | c.1499A>G p.Y500C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV100250406; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID2 | c.3617C>T p.T1206M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as rs371554995, COSV57599537; called by muse, mutect2, varscan2
- ARL2 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99880459; called by muse, mutect2, varscan2
- ARMC8 | c.1526G>A p.R509Q (on ENST00000469044 / NM_001363941.2; = p.R495Q on NM_015396.6) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV58624128; called by muse, mutect2, varscan2
- ARMCX3 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100362186; called by muse, mutect2, varscan2
- ARSA | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV99332278; called by muse, mutect2
- ARSJ | c.1391G>A p.S464N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.665); catalogued as COSV59538451; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAP1 | c.2902C>A p.L968M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100726857; called by muse, mutect2, varscan2
- ASH1L | c.7018C>T p.P2340S (on ENST00000368346 / NM_001366177.2; = p.P2335S on NM_018489.3) | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100853136; called by muse, mutect2
- ASL | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1428029508, CM141229, COSV100508825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASL | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173674993, COSV59188488; called by muse, mutect2, varscan2
- ASNSD1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765679662, COSV53624688; called by muse, mutect2, varscan2
- ASXL3 | c.5752G>A p.G1918S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs768844047, COSV52464335; called by muse, mutect2, varscan2
- ATAD5 | c.3892G>A p.A1298T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100429673; called by muse, mutect2
- ATF7 | c.538C>A p.L180I (on ENST00000548446 / NM_001366555.2; = p.L169I on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV100129178; called by muse, mutect2
- ATG2A | c.4715G>A p.G1572D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV101033890; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs771531141; called by mutect2, varscan2
- ATG3 | c.221del p.L74Wfs*2 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as COSV51926597; called by mutect2, pindel, varscan2
- ATG9A | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs61747685, COSV100772500; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs770350293; called by mutect2, pindel, varscan2
- ATN1 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs782778482, COSV63113343; called by mutect2, varscan2
- ATP11A | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as rs1425060161, COSV52121151, COSV52125601; called by muse, mutect2, varscan2
- ATP11B | c.2747A>G p.Y916C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100017530; called by muse, mutect2, varscan2
- ATP11C | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as rs868182848, COSV100990087; called by muse, mutect2, varscan2
- ATP1B2 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs532742015, COSV51515302; called by muse, mutect2
- ATP1B4 | c.394T>C p.Y132H (on ENST00000218008 / NM_001142447.3; = p.Y128H on NM_012069.5) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99486161; called by muse, mutect2, varscan2
- ATP2A3 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375267586; called by muse, mutect2, varscan2
- ATP2C1 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs142641883; called by muse, mutect2, varscan2
- ATP6V0B | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs775714078, COSV52544188; called by muse, mutect2, varscan2
- ATP7A | c.1814A>G p.H605R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs1020034878, COSV100430285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7B | c.3106G>A p.V1036I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs761147984, CM087673, COSV54438958; ClinVar: uncertain significance; called by mutect2, varscan2
- ATP9A | c.617G>A p.C206Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as rs1272330279, COSV100124357, COSV58771495; called by muse, mutect2, varscan2
- ATRX | c.5478C>A p.F1826L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100970118; called by muse, mutect2
- ATRX | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs782757975, COSV64876086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATXN7L3 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV101231726; called by muse, mutect2
- AURKB | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV60245973; called by muse, mutect2, varscan2
- AWAT1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765416872, COSV100997176; called by muse, mutect2, varscan2
- AWAT2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs180949354, COSV52144204; called by muse, mutect2, varscan2
- AXIN1 | c.2371G>A p.G791R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs980697628, COSV51985484, COSV99249313; called by muse, mutect2, varscan2
- AXIN1 | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs781493273, COSV99249314; called by muse, varscan2
- AXIN2 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as rs1555577386, COSV100195953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALT4 | c.30_32del p.L11del | In Frame Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs758140605; called by mutect2, pindel, varscan2
- B4GALNT4 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100327214; called by muse, mutect2, varscan2
- B4GALT5 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406837691, COSV65493257; called by mutect2, varscan2
- BACH1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202019525; called by muse, mutect2, varscan2
- BANK1 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774795790, COSV59840190, COSV59852271; called by mutect2, varscan2
- BAP1 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1272136993, COSV99963446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAP1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as rs535796204, COSV56240233, COSV99963448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARD1 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs767208122, COSV53617924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAX | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV53169319; called by muse, mutect2, varscan2
- BAZ2B | c.3103C>T p.R1035C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1293061266, COSV99680867; called by muse, mutect2
- BCAN | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs759486942, COSV61257438; called by muse, mutect2, varscan2
- BCAN | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs550450698, COSV61258114; called by muse, mutect2, varscan2
- BCAN | c.2483G>A p.G828D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100227889; called by muse, mutect2, varscan2
- BCAR1 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs746131932, COSV99366048; called by muse, mutect2, varscan2
- BCL6 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs778509539, COSV51650382; called by muse, mutect2, varscan2
- BCL7A | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs780831032, COSV55852978; called by muse, mutect2, varscan2
- BCR | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.499); catalogued as COSV100005999; called by muse, mutect2, varscan2
- BDH1 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs201898088; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs752427670; called by mutect2, varscan2
- BEND2 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV101191815, COSV101191908; called by muse, mutect2, varscan2
- BFSP2 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV56589533; called by muse, mutect2
- BGLAP | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs777313170, COSV99430770; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs755506199; called by mutect2, varscan2
- BIN1 | c.1480G>A p.V494M (on ENST00000316724 / NM_001320642.1; = p.V355M on NM_004305.4) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as rs144459969, COSV52123129; called by muse, mutect2, varscan2
- BIN2 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769343422, COSV99909189; called by muse, mutect2, varscan2
- BIRC6 | c.5002G>T p.A1668S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV101427862; called by muse, mutect2, varscan2
- BIRC6 | c.13181C>T p.A4394V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101427863; called by muse, mutect2, varscan2
- BLMH | c.313del p.W105Gfs*11 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as COSV55587541; called by mutect2, pindel
- BMP15 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as rs782239259, COSV53140851; called by muse, mutect2, varscan2
- BMP2K | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99784852; called by muse, mutect2, varscan2
- BMPER | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs376351419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR1B | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs377000102, COSV52777569, COSV52777734; called by muse, mutect2, varscan2
- BOD1L1 | c.8836C>T p.R2946W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs779870948, COSV99238453; called by muse, mutect2, varscan2
- BOLA1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148563158, COSV99053804; called by mutect2, varscan2
- BPNT2 | c.739G>T p.G247W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99388841; called by muse, mutect2, varscan2
- BRAF | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs769648920, COSV56273855; called by muse, mutect2, varscan2
- BRCA1 | c.4643C>T p.T1548M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs273900737, COSV58788973; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRD2 | c.2214G>T p.K738N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV100875566; called by muse, mutect2
- BRINP2 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.11); catalogued as COSV100837846; called by muse, mutect2, varscan2
- BRINP2 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774295051, COSV64176270; called by muse, varscan2
- BRS3 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101036360, COSV65711214; called by muse, mutect2, varscan2
- BSN | c.4615C>T p.R1539* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99607362; called by muse, mutect2, varscan2
- BSN | c.10288G>A p.A3430T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1300328552, COSV99607364; called by muse, mutect2
- BST2 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1285913459, COSV99392036; called by muse, mutect2, varscan2
- BTAF1 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs749503011, COSV99794945; called by muse, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs752512017; called by mutect2, varscan2
- BTD | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs764770052, COSV100329431; called by muse, mutect2, varscan2
- BTN2A1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV100438386; called by muse, mutect2, varscan2
- BTN3A2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100709561; called by muse, mutect2, varscan2
- BYSL | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100026912; called by muse, mutect2
- C10orf120 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs531792820, COSV61492799; called by muse, mutect2, varscan2
- C12orf42 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV100171813; called by muse, mutect2, varscan2
- C12orf65 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV99473852; called by mutect2, varscan2
- C14orf93 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); catalogued as COSV100136601; called by muse, mutect2, varscan2
- C15orf39 | c.580del p.V194Cfs*132 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs749135337, COSV100641311; called by mutect2, pindel, varscan2
- C16orf46 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1226955702, COSV100215120; called by muse, mutect2, varscan2
- C16orf54 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV61477050; called by muse, mutect2, varscan2
- C1QTNF6 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774652920, COSV99742172; called by mutect2, varscan2
- C1orf112 | c.563+3_563+6del p.X188_splice | Splice Site (DEL) | VAF 8/24 reads (33%) | catalogued as rs1405423121; called by pindel, varscan2
- C21orf58 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV99387919; called by muse, mutect2
- C21orf62 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV101212291; called by muse, mutect2, varscan2
- C2CD2L | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756667125, COSV100371079; called by muse, mutect2, varscan2
- C2CD3 | c.2293C>A p.L765I | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV100486270; called by muse, mutect2, varscan2
- C2orf69 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs780651524, COSV100178697; called by muse, mutect2, varscan2
- C3orf18 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs559763162, COSV51750082; called by muse, mutect2, varscan2
- C5 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs144876205; called by muse, mutect2, varscan2
- C6 | c.1685-2A>G p.X562_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99666531; called by mutect2, varscan2
- C7orf31 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191500428, COSV99383765; called by muse, mutect2, varscan2
- C8orf58 | c.1072C>T p.R358* (on ENST00000289989 / NM_001013842.3; = p.R350* on NM_173686.3) | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs371650009; called by muse, mutect2, varscan2
- CA3 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs369670663; called by muse, mutect2, varscan2
- CABIN1 | c.5601G>A p.W1867* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as rs1247026739, COSV99572743; called by muse, mutect2
- CABP7 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs377697121; called by muse, mutect2, varscan2
- CACHD1 | c.3704del p.P1235Lfs*7 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs764948820; called by mutect2, pindel, varscan2
- CACNA1C | c.6329C>T p.A2110V (on ENST00000399634 / NM_001167625.1; = p.A2039V on NM_000719.7) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs549476254, COSV59708098, COSV59761534; called by muse, mutect2, varscan2
- CACNA1D | c.5105A>G p.Q1702R (on ENST00000350061 / NM_001128840.3; = p.Q1722R on NM_000720.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV99856681; called by muse, mutect2, varscan2
- CACNA1F | c.5300del p.P1767Rfs*165 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as COSV59904688; called by mutect2, pindel, varscan2
- CACNA1G | c.4027C>T p.R1343W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100661215; called by muse, mutect2, varscan2
- CACNA1H | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs1208640164, COSV62005637; called by muse, mutect2, varscan2
- CACNA1I | c.2666A>T p.D889V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV100359304; called by muse, mutect2, varscan2
- CACNA1I | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100359310; called by muse, mutect2
- CACNA2D1 | c.3145C>T p.Q1049* (on ENST00000356253 / NM_001366867.1; = p.Q1037* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100665989; called by muse, varscan2
- CACNA2D2 | c.2369A>G p.Y790C (on ENST00000479441 / NM_001174051.3; = p.Y783C on NM_006030.4) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99816928; called by muse, mutect2, varscan2
- CACNG3 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV99135443; called by muse, mutect2, varscan2
- CAD | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.624); catalogued as rs769349785, COSV53031477; called by muse, mutect2, varscan2
- CAMTA2 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs147120771; called by muse, mutect2, varscan2
- CAPN12 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs539611909, COSV61019206; called by mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARD17 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs553449901, COSV100995176, COSV65215715; called by muse, mutect2, varscan2
- CARF | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.154); catalogued as COSV100247505; called by muse, mutect2, varscan2
- CARMIL2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1428762094, COSV100575957; called by muse, mutect2, varscan2
- CASD1 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99802302; called by muse, mutect2, varscan2
- CASP1 | c.701T>C p.F234S (on ENST00000436863 / NM_033292.4; = p.F213S on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100782722; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs765105588; called by mutect2, varscan2
- CASP8 | c.697C>T p.R233W (on ENST00000432109 / NM_033355.3; = p.R250W on NM_001228.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760898260, COSV51846938; called by muse, varscan2
- CBLL1 | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs750032451, COSV99755441; called by muse, mutect2, varscan2
- CCDC114 | c.1277C>A p.A426D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100196386; called by muse, mutect2, varscan2
- CCDC136 | c.2521G>T p.A841S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.597); catalogued as COSV99922196; called by muse, mutect2, varscan2
- CCDC17 | c.1437G>A p.W479* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100601625; called by muse, mutect2
- CCDC186 | c.2161G>T p.G721* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100991090; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC51 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99602290; called by muse, mutect2, varscan2
- CCDC60 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV100554645; called by muse, mutect2, varscan2
- CCDC61 | c.299T>C p.M100T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs1568690676, COSV99625307; called by muse, mutect2, varscan2
- CCDC80 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs747085670, COSV99244316; called by muse, mutect2, varscan2
- CCDC88A | c.3603-3del | Splice Region (DEL) | VAF 15/59 reads (25%) | catalogued as rs768846308; called by pindel, varscan2
- CCDC88C | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV101105147; called by muse, mutect2
- CCKAR | c.149T>C p.L50S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99810147; called by muse, mutect2, varscan2
- CCKBR | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV100583044, COSV58098456; called by muse, mutect2, varscan2
- CCNJ | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs1421285696, COSV99796165; called by muse, mutect2, varscan2
- CCNL2 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101275647; called by muse, mutect2, varscan2
- CCT7 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs773269403, COSV54584844, COSV99240548; called by muse, mutect2, varscan2
- CD180 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.718); catalogued as COSV99842088; called by muse, mutect2, varscan2
- CD1D | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100939549; called by muse, mutect2, varscan2
- CD320 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs57195458, COSV56848296; called by muse, mutect2, varscan2
- CD37 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs961520984, COSV60544768; called by muse, mutect2, varscan2
- CD44 | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1275247017, COSV99555439; called by muse, mutect2, varscan2
- CD9 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as rs929350862, COSV99152794; called by muse, mutect2, varscan2
- CDC25A | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs149642245; called by muse, mutect2, varscan2
- CDCA2 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as rs1396382891, COSV55340313; called by muse, mutect2, varscan2
- CDH20 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs762896499, COSV53010082, COSV53016279; called by muse, mutect2, varscan2
- CDHR2 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.134); catalogued as COSV99991054; called by muse, mutect2, varscan2
- CDK16 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs727503845, COSV99331447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK6 | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV99720743; called by muse, mutect2, varscan2
- CDKL2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs1158297639, COSV56732728; called by muse, mutect2, varscan2
- CDKN1A | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs774390644, COSV55189534; called by muse, mutect2, varscan2
- CDKN2B | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.01); catalogued as COSV99439449; called by muse, mutect2, varscan2
- CDON | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99700644; called by muse, mutect2, varscan2
- CDYL2 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101629512; called by muse, mutect2, varscan2
- CEACAM7 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs782496203, COSV50072517, COSV50073426; called by muse, mutect2, varscan2
- CEBPZ | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV50017460; called by muse, mutect2, varscan2
- CELA3B | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs148634740; called by muse, mutect2, varscan2
- CELF6 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); catalogued as rs763073658, COSV99763590; called by muse, mutect2, varscan2
- CELSR1 | c.2935C>A p.L979I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV53090678, COSV99416932; called by muse, mutect2
- CELSR3 | c.7633G>A p.V2545M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.86); catalogued as rs756781285, COSV99372623; called by muse, mutect2, varscan2
- CEMIP | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.323); catalogued as rs1381076537, COSV99586135; called by muse, mutect2
- CENPB | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.889); catalogued as COSV100713311; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPU | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV99859751; called by muse, mutect2, varscan2
- CEP135 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as rs1476764151, COSV99954129; called by muse, mutect2
- CEP152 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV100358529; called by muse, mutect2, varscan2
- CEP162 | c.3847C>T p.R1283* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs1191200730, COSV100002406; called by muse, mutect2, varscan2
- CEP250 | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100698754; called by muse, mutect2
- CEP290 | c.7066G>A p.A2356T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.333); catalogued as rs767697315, COSV100467885; called by muse, mutect2, varscan2
- CEP43 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs377028909, COSV62760903; called by muse, mutect2, varscan2
- CFAP100 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs762062611, COSV100729080; called by muse, mutect2, varscan2
- CFAP100 | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs759274696, COSV61504556; called by muse, mutect2, varscan2
- CFAP20DC | c.2170C>T p.P724S (on ENST00000482387 / NM_001351530.2; = p.P473S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as COSV99918109; called by muse, mutect2, varscan2
- CFAP47 | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV52885562, COSV99934429; called by muse, mutect2, varscan2
- CFAP47 | c.5095G>A p.A1699T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as COSV100544972; called by muse, mutect2, varscan2
- CFAP65 | c.3889G>A p.V1297M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100444642; called by muse, mutect2, varscan2
- CFAP65 | c.542G>T p.R181M (on ENST00000341552 / NM_194302.4; = p.R116M on NM_152389.4) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99838233; called by muse, mutect2, varscan2
- CHCHD3 | c.453+1G>A p.X151_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99365632; called by muse, mutect2, varscan2
- CHCHD6 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs1019174450, COSV99335679; called by muse, mutect2, varscan2
- CHD4 | c.3917G>A p.R1306Q (on ENST00000357008 / NM_001363606.2; = p.R1319Q on NM_001273.5) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58906540; called by muse, mutect2, varscan2
- CHD6 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV58557125; called by muse, mutect2, varscan2
- CHD6 | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs764370036, COSV100497799; called by muse, mutect2
- CHD7 | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs745837768, COSV101418015; called by muse, mutect2, varscan2
- CHD7 | c.8213C>T p.T2738M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs761409446, COSV71109597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD8 | c.3720G>T p.Q1240H (on ENST00000646647 / NM_001170629.2; = p.Q961H on NM_020920.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101303043; called by muse, mutect2, varscan2
- CHI3L1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as COSV99703799; called by muse, mutect2, varscan2
- CHKA | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs759719763, COSV99694008; called by muse, mutect2, varscan2
- CHORDC1 | c.663del p.D222Mfs*36 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs1361626211; called by mutect2, pindel, varscan2
- CHRM3 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99697586; called by muse, mutect2, varscan2
- CHRM4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1309986933, COSV100708732; called by muse, mutect2, varscan2
- CHRNA3 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100467867; called by muse, mutect2, varscan2
- CHST2 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs868587203, COSV58885213; called by muse, mutect2, varscan2
- CHST5 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60340965; called by muse, mutect2, varscan2
- CHST5 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs577930949, COSV60338664; called by muse, mutect2, varscan2
- CHST8 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs147618925; called by muse, mutect2, varscan2
- CIAO3 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs778425484, COSV52405589; called by muse, mutect2, varscan2
- CIAO3 | c.1014G>T p.E338D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs866024721, COSV99284573; called by muse, mutect2, varscan2
- CIBAR1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs201718859, COSV63896699; called by muse, mutect2, varscan2
- CIC | c.4072C>T p.R1358C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99359019; called by muse, mutect2
- CIITA | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs182369772; called by muse, mutect2, varscan2
- CILP | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as rs201015610, COSV56025993; called by muse, mutect2, varscan2
- CIT | c.5920C>T p.R1974C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1016583716, COSV99948456; called by muse, mutect2, varscan2
- CLASP1 | c.3815C>T p.A1272V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV99753171; called by muse, mutect2
- CLASP1 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs763851949, COSV55320925; called by muse, mutect2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs761731080; called by mutect2, varscan2
- CLEC14A | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.093); catalogued as COSV100643499; called by mutect2, varscan2
- CLEC4A | c.284del p.N95Ifs*49 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs760557093; called by mutect2, varscan2
- CLNK | c.80del p.N27Tfs*17 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1430451531; called by mutect2, pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs369752219; called by mutect2, varscan2
- CLP1 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.148); catalogued as rs760641774, COSV57055029, COSV57055598; called by muse, mutect2, varscan2
- CLSTN2 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs753618039, COSV71719290; called by muse, mutect2, varscan2
- CLUH | c.1364G>A p.G455D (on ENST00000435359; = p.G493D on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101425636, COSV70929364; called by muse, mutect2, varscan2
- CMYA5 | c.4819C>T p.P1607S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV101483855; called by muse, mutect2, varscan2
- CMYA5 | c.12013C>T p.R4005C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs780702412, COSV69746351; called by muse, mutect2, varscan2
- CNGB1 | c.2989C>T p.R997C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781615372, COSV51901505; called by muse, mutect2, varscan2
- CNN3 | c.816C>A p.Y272* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as COSV99597847; called by muse, mutect2, varscan2
- CNNM1 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as rs750830486, COSV100763768; called by muse, varscan2
- CNNM1 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as rs771574660, COSV99054486; called by muse, mutect2, varscan2
- CNNM4 | c.1921A>G p.T641A | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100998600; called by muse, mutect2, varscan2
- CNOT3 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201217351, COSV55362332, COSV99651517; called by muse, mutect2, varscan2
- CNOT6L | c.455G>A p.R152Q (on ENST00000504123 / NM_001286790.2; = p.R147Q on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs781330689, COSV53699998; called by mutect2, varscan2
- CNTLN | c.4175del p.K1392Rfs*3 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs747411468; called by mutect2, pindel, varscan2
- CNTN2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs1422381117, COSV100084691; called by muse, mutect2, varscan2
- CNTN3 | c.2977C>T p.R993* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs757006391, COSV55162682; called by muse, mutect2, varscan2
- CNTN4 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs766409827, COSV100638863; called by muse, mutect2, varscan2
- CNTNAP2 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV62274847; called by muse, mutect2, varscan2
- COL10A1 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV99684077; called by muse, mutect2, varscan2
- COL11A1 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100615271, COSV62184895; called by muse, mutect2
- COL12A1 | c.6902C>A p.P2301Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100485437; called by muse, mutect2, varscan2
- COL12A1 | c.4280G>A p.R1427H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.652); catalogued as rs1033545876, COSV100485438; called by muse, mutect2, varscan2
- COL18A1 | c.2461G>A p.E821K (on ENST00000359759 / NM_130444.3; = p.E586K on NM_030582.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs766573503, COSV100700467; called by muse, mutect2, varscan2
- COL1A2 | c.3326A>G p.D1109G | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV51963293; called by muse, mutect2, varscan2
- COL22A1 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.413); catalogued as rs747819697, COSV57339361; called by muse, mutect2, varscan2
- COL22A1 | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100276489, COSV57333300; called by muse, mutect2, varscan2
- COL22A1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141938188, COSV57333337; called by muse, mutect2, varscan2
- COL24A1 | c.3658G>A p.E1220K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100992918; called by muse, mutect2
- COL27A1 | c.1798T>G p.S600A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.755); catalogued as COSV100620745, COSV61931523; called by muse, varscan2
- COL4A2 | c.4954G>A p.A1652T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.942); catalogued as rs763103910, COSV100847246, COSV64633658; called by muse, mutect2, varscan2
- COL4A4 | c.4693C>T p.R1565C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372161135, CM1414090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A4 | c.2654G>A p.G885D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425028482, COSV100306261; called by muse, mutect2, varscan2
- COL4A6 | c.353G>T p.R118I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100563405; called by mutect2, varscan2
- COL6A6 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100649845; called by muse, mutect2, varscan2
- COL8A1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as rs758122778, COSV53740388, COSV99657215; called by muse, mutect2, varscan2
- COL9A1 | c.1611+1G>T p.X537_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100294118; called by muse, mutect2, varscan2
- COPA | c.2579A>G p.E860G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99614696; called by muse, mutect2, varscan2
- COQ4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as rs762170679, COSV100306631; called by muse, mutect2, varscan2
- COQ6 | c.1277C>A p.A426D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99473761; called by muse, mutect2, varscan2
- CORO1A | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); catalogued as rs1343968093, COSV99531818; called by muse, mutect2
- CORO7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs527794334, COSV52031064; called by muse, mutect2, varscan2
- COX5B | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 70/129 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV99300233; called by muse, mutect2, varscan2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs750161916, COSV71597321; called by mutect2, pindel, varscan2
- CPD | c.2614C>T p.R872* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99852485; called by muse, mutect2, varscan2
- CPEB2 | c.2889G>A p.M963I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.113); catalogued as COSV99469967; called by muse, mutect2, varscan2
- CPT1B | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as rs750222036, COSV100376485; called by muse, mutect2, varscan2
- CPVL | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99605392; called by muse, mutect2, varscan2
- CR1 | c.3309G>T p.K1103N | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.385); catalogued as rs774860182, COSV100887403; called by muse, mutect2, varscan2
- CRAT | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100539824; called by muse, mutect2, varscan2
- CRB1 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as COSV100958375, COSV66338693; called by muse, mutect2, varscan2
- CRHBP | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs190988381, COSV57187683; called by muse, mutect2, varscan2
- CRISPLD2 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776142449, COSV99295390; called by muse, mutect2, varscan2
- CRYBG1 | c.4831C>T p.R1611W | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373859652; called by muse, mutect2, varscan2
- CRYBG1 | c.5672G>A p.C1891Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100954404; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs747248693; called by mutect2, varscan2
- CSAD | c.1282C>T p.P428S (on ENST00000444623 / NM_001244705.2; = p.P455S on NM_015989.5) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV99914515; called by muse, mutect2, varscan2
- CSH2 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs570707903, COSV61080072, COSV61081106; called by muse, varscan2
- CSMD1 | c.3753G>T p.M1251I (on ENST00000520002; = p.M1250I on NM_033225.6) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV59366171; called by muse, mutect2, varscan2
- CSMD2 | c.4664G>A p.R1555Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs922339512, COSV53912486; called by muse, mutect2, varscan2
- CSMD3 | c.10378A>G p.T3460A (on ENST00000297405 / NM_001363185.1; = p.T3291A on NM_052900.3) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99825615; called by muse, mutect2
- CSNK2A2 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV99345155; called by muse, mutect2, varscan2
- CSTF3 | c.613del p.M205* | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs1300471016; called by mutect2, pindel, varscan2
- CTAGE6 | c.1340C>A p.T447N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749275592, COSV101417806; called by muse, mutect2, varscan2
- CTBS | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV99759627; called by muse, mutect2, varscan2
- CTNNA1 | c.1296G>A p.E432= | Splice Region (SNP) | VAF 12/53 reads (23%) | catalogued as rs1397271124, COSV100242211; called by muse, mutect2, varscan2
- CTNNAL1 | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs144835474; called by muse, mutect2, varscan2
- CTNNBL1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs769100178, COSV63743763; called by mutect2, varscan2
- CTTN | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV100097181, COSV57236699; called by muse, mutect2, varscan2
- CUBN | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs746956601, COSV100911750; called by muse, mutect2, varscan2
- CUTA | c.77C>T p.A26V (on ENST00000488034 / NM_001014840.2; = p.A3V on NM_015921.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99537862; called by muse, mutect2, varscan2
- CUX1 | c.1321G>A p.A441T (on ENST00000437600 / NM_181500.4; = p.A443T on NM_001913.5) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs781925170, COSV52939199; called by muse, mutect2, varscan2
- CWC22 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs538460267, COSV55427111, COSV55430619; called by mutect2, varscan2
- CXorf56 | c.587C>T p.A196V (on ENST00000536133 / NM_001170570.2; = p.A210V on NM_022101.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.281); catalogued as rs764134233, COSV100233328; called by muse, mutect2, varscan2
- CYFIP2 | c.3587G>A p.R1196H (on ENST00000616178 / NM_001291722.2; = p.R1171H on NM_014376.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs780179999, COSV100555682; called by muse, mutect2, varscan2
- CYP11A1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202246326, COSV51432297; called by muse, mutect2, varscan2
- CYP19A1 | c.828G>T p.M276I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99547322; called by muse, mutect2, varscan2
- CYP1A1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs201174966, COSV65697096; called by muse, mutect2, varscan2
- CYP20A1 | c.972A>T p.R324S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100619004; called by muse, mutect2, varscan2
- CYP2R1 | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584853; called by muse, mutect2
- CYP4A22 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.05); catalogued as rs749138787, COSV99594608; called by muse, mutect2, varscan2
- CYP4V2 | c.571del p.Y191Tfs*7 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs1467050790; called by pindel, varscan2
- DAAM2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs753445244, COSV51418754; called by muse, mutect2, varscan2
- DAB2IP | c.3002G>A p.R1001H (on ENST00000408936; = p.R973H on NM_032552.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1211930144, COSV52265295; called by muse, varscan2
- DACH2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV64188049; called by muse, mutect2
- DAPK3 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100009460; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | catalogued as COSV99245498; called by mutect2, varscan2
- DBNL | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs376675318, COSV99803500; called by muse, mutect2, varscan2
- DCAF11 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs373798935; called by muse, mutect2, varscan2
- DCAF12L1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100948105; called by muse, mutect2, varscan2
- DCAF4L1 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs1408483281, COSV100295544; called by muse, mutect2, varscan2
- DCAF7 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV100177537; called by muse, mutect2
- DCLK3 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV101373878, COSV69363496; called by muse, mutect2, varscan2
- DCN | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1318907487, COSV99271833; called by muse, mutect2
- DDA1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100724753; called by muse, mutect2, varscan2
- DDX28 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100192887; called by muse, mutect2, varscan2
- DDX39A | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs1360378048, COSV99660155; called by muse, mutect2, varscan2
- DDX39B | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100385341; called by muse, mutect2
- DENND10 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.213); catalogued as rs942250644, COSV100813968; called by muse, mutect2
- DENND3 | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs758856671, COSV52804642; called by muse, mutect2, varscan2
- DENND5B | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1200226104, COSV60907541; called by muse, mutect2
- DENND6B | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs749223526, COSV101306023; called by muse, varscan2
- DGKD | c.3034G>A p.A1012T (on ENST00000264057 / NM_152879.3; = p.A968T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs755394472, COSV99895455, COSV99896055; called by muse, mutect2, varscan2
- DGKK | c.2651A>G p.Q884R | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV101052886; called by muse, mutect2, varscan2
- DHCR7 | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV100831727; called by muse, mutect2, varscan2
- DHPS | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52952821, COSV99269511; called by muse, mutect2, varscan2
- DHRS13 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs201593315, COSV66683835; called by muse, mutect2, varscan2
- DHRS9 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV100513332; called by muse, mutect2, varscan2
- DHX33 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs144497363; called by muse, mutect2, varscan2
- DHX35 | c.1680G>T p.K560N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV99326450; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs373108427; called by mutect2, varscan2
- DHX38 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs565963668, COSV51697452; called by muse, mutect2, varscan2
- DHX9 | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.832); catalogued as rs1302395270, COSV62362167; called by muse, mutect2, varscan2
- DIAPH2 | c.1864C>A p.L622I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV100230907; called by mutect2, varscan2
- DIAPH3 | c.2277G>T p.K759N (on ENST00000400324 / NM_001042517.2; = p.K496N on NM_030932.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV99932821; called by muse, mutect2
- DIDO1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs945073284, COSV99824856; called by muse, mutect2, varscan2
- DIP2A | c.1753A>G p.M585V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100595214; called by muse, mutect2, varscan2
- DIPK1B | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs1362193457, COSV100765435; called by muse, mutect2, varscan2
- DIRAS3 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779782596, COSV100921301; called by muse, mutect2, varscan2
- DIS3 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.615); catalogued as COSV100899826; called by muse, mutect2, varscan2
- DIS3L2 | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV99805534; called by muse, mutect2, varscan2
- DKK3 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100484926; called by muse, mutect2, varscan2
- DLG1 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs945330889, COSV100014663; called by muse, mutect2, varscan2
- DLG5 | c.3779G>A p.R1260H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs777517878, COSV64947845; called by muse, mutect2, varscan2
- DLL1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs200887016; called by muse, mutect2
- DLL1 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as rs1409058694, COSV64538807; called by muse, mutect2, varscan2
- DLL3 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.636); catalogued as rs919771434, COSV52693383; called by muse, mutect2, varscan2
- DMBT1 | c.6928G>A p.G2310S (on ENST00000338354 / NM_001377530.1; = p.G1553S on NM_004406.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs752458397, COSV100352181; called by muse, mutect2, varscan2
- DMXL2 | c.4999G>A p.A1667T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99195981; called by muse, mutect2, varscan2
- DNAAF4 | c.430del p.I144* | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | catalogued as rs755135568; called by mutect2, pindel, varscan2
- DNAAF4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as rs1301874266, COSV100336595; called by muse, mutect2, varscan2
- DNAH3 | c.7318C>T p.R2440W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551993850, COSV54543241; called by muse, mutect2, varscan2
- DNAH8 | c.11729T>C p.L3910P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100543415; called by muse, mutect2, varscan2
- DNAH8 | c.12376A>G p.K4126E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100543416; called by muse, mutect2
- DNAH9 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs765666122, COSV52379331; called by muse, mutect2, varscan2
- DNAH9 | c.4103G>A p.S1368N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99304275; called by muse, mutect2, varscan2
- DNAH9 | c.10096G>A p.V3366M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1003074223, COSV52344207; called by muse, mutect2, varscan2
- DNAJB2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs143306245, COSV55346351; called by muse, varscan2
- DNAJC13 | c.4549G>A p.V1517I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772420158, COSV53451529; called by muse, mutect2, varscan2
- DNAJC16 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.217); catalogued as rs753607084, COSV65448329; called by muse, mutect2, varscan2
- DNM2 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs202155679; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DNMBP | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as rs370012463, COSV100143560; called by muse, mutect2, varscan2
- DNMT1 | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs1290055474, COSV61576491; called by muse, mutect2, varscan2
- DOCK1 | c.4888_4889insT p.R1630Lfs*60 | Frame Shift Ins (INS) | VAF 7/72 reads (10%) | catalogued as COSV99726924; called by mutect2, pindel, varscan2
- DOCK11 | c.1473C>A p.H491Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.572); catalogued as rs1426046732, COSV99352953; called by muse, mutect2, varscan2
- DOCK11 | c.5014A>G p.N1672D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52240501; called by muse, mutect2, varscan2
- DOCK2 | c.3212G>A p.R1071H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs750051021, COSV56948722; called by muse, mutect2, varscan2
- DOCK3 | c.2421G>T p.E807D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99809308; called by muse, mutect2, varscan2
- DOCK3 | c.5063C>T p.A1688V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs778025492, COSV56518061; called by muse, mutect2, varscan2
- DOCK6 | c.5957G>A p.R1986Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV53918129; called by muse, mutect2, varscan2
- DOCK8 | c.2365G>A p.V789M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs531535885, COSV66617192; called by muse, mutect2, varscan2
- DOCK9 | c.30_32del p.S10del | In Frame Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs1567159626; called by pindel, varscan2
- DOLK | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.059); catalogued as COSV101001205; called by muse, mutect2, varscan2
- DOP1A | c.3473G>C p.C1158S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.053); catalogued as COSV99381018; called by muse, mutect2, varscan2
- DOP1B | c.5783G>A p.R1928H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs138227303; called by muse, mutect2, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs748560644; called by mutect2, pindel, varscan2
- DPY19L1 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1409703849, COSV60583729; called by muse, mutect2, varscan2
- DPYD | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs777560627, COSV64603563; called by muse, mutect2, varscan2
- DPYSL4 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.879); catalogued as rs1398044644, COSV100633839, COSV58308329; called by muse, mutect2
- DRP2 | c.2636C>T p.T879I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101235133; called by muse, mutect2, varscan2
- DSCAM | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs777330549, COSV68021474, COSV68028999, COSV68036585; called by muse, mutect2, varscan2
- DSCC1 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV100558248; called by muse, mutect2
- DSEL | c.3599A>G p.E1200G | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100025301; called by muse, mutect2, varscan2
- DVL2 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219101427, COSV99138335; called by mutect2, varscan2
- DYNC1H1 | c.12526C>T p.R4176C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64142003; called by muse, mutect2
- DYNC2H1 | c.7750G>A p.A2584T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1167083215, COSV100517617; called by muse, mutect2, varscan2
- DYNC2H1 | c.9107G>T p.S3036I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100517619; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs751377941; called by mutect2, varscan2
- DYSF | c.2285A>G p.H762R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV99244524; called by muse, mutect2, varscan2
- DYSF | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754179180, COSV99244529; called by muse, mutect2, varscan2
- E2F7 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100523319; called by muse, mutect2, varscan2
- EBPL | c.557A>C p.Q186P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99665524; called by muse, mutect2, varscan2
- ECD | c.1709C>A p.P570H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV100624679; called by muse, mutect2, varscan2
- ECEL1 | c.2294C>A p.P765H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100458470; called by muse, mutect2, varscan2
- EDAR | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV99303114; called by muse, mutect2, varscan2
- EDIL3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.837); catalogued as COSV99674877; called by muse, mutect2, varscan2
- EDRF1 | c.7del p.D3? | Frame Shift Del (DEL) | VAF 27/103 reads (26%) | catalogued as COSV100524106; called by mutect2, pindel, varscan2
- EEF1AKMT3 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100103485; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs138050343; called by muse, mutect2, varscan2
- EEF2K | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as rs757485312, COSV99532383, COSV99532627; called by muse, mutect2, varscan2
- EFCAB6 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99412507; called by muse, mutect2, varscan2
- EFNA4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as rs200331554, COSV63018009; called by muse, mutect2, varscan2
- EFTUD2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53656001; called by muse, mutect2, varscan2
- EFTUD2 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68182900; called by muse, mutect2, varscan2
- EGR1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53522307; called by muse, mutect2, varscan2
- EHD2 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs951479746, COSV99621649; called by muse, mutect2, varscan2
- EIF1AD | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV100381337; called by muse, mutect2, varscan2
- EIF2B3 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV100838900; called by mutect2, varscan2
- EIF3G | c.840+2T>C p.X280_splice | Splice Site (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99460854; called by muse, mutect2, varscan2
- EIF3G | c.712_714del p.N238del | In Frame Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs758688972; called by pindel, varscan2
- EIF3H | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99411467; called by muse, mutect2, varscan2
- EIF4A2 | c.70A>T p.I24F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); catalogued as COSV100125330; called by muse, mutect2, varscan2
- EIF4G3 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99943314; called by muse, mutect2
- ELAPOR1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.882); catalogued as rs756493200, COSV64046782; called by muse, mutect2, varscan2
- ELAPOR1 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs1213321643, COSV100884405; called by muse, mutect2, varscan2
- ELAVL4 | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100836572; called by muse, mutect2, varscan2
- ELAVL4 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100836573; called by muse, mutect2, varscan2
- ELK3 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs1295166133, COSV99957488; called by muse, mutect2, varscan2
- ELMO3 | c.2174G>A p.R725Q (on ENST00000652269; = p.R672Q on NM_024712.5) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as rs375483363; called by muse, mutect2, varscan2
- ELP3 | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV99833804; called by muse, mutect2, varscan2
- ELP4 | c.868C>T p.R290C (on ENST00000350638; = p.R289C on NM_019040.5) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768750746, COSV63351732; called by mutect2, varscan2
- EMILIN1 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100980138; called by muse, mutect2, varscan2
- EMILIN2 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs768102952, COSV54424565; called by muse, mutect2, varscan2
- EML5 | c.4123G>A p.D1375N (on ENST00000380664; = p.D1383N on NM_183387.3) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100715007, COSV100715068; called by muse, mutect2, varscan2
- EML5 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV61345274; called by muse, mutect2, varscan2
- EMX1 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754890777, COSV50689172; called by muse, mutect2, varscan2
- ENG | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100785215; called by muse, mutect2
- ENO2 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as rs373556957; called by muse, mutect2
- ENO3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as rs756594079, COSV52776532; called by muse, mutect2, varscan2
- ENOX2 | c.149C>T p.A50V (on ENST00000338144 / NM_001382520.1; = p.A21V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100583796; called by muse, mutect2, varscan2
- ENTPD6 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs1354930689, COSV100736981; called by muse, mutect2, varscan2
- EP400 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100200478; called by muse, mutect2
- EP400 | c.8380C>T p.Q2794* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV57787037; called by muse, mutect2, varscan2
- EPB41L4B | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.771); catalogued as rs753889477, COSV65798762; called by muse, mutect2, varscan2
- EPG5 | c.3910G>A p.D1304N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99956550; called by muse, mutect2, varscan2
- EPHA1 | c.2661_2662insA p.H888Tfs*10 | Frame Shift Ins (INS) | VAF 19/69 reads (28%) | catalogued as COSV99313528; called by mutect2, pindel, varscan2
- EPHA2 | c.2602G>A p.V868I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs1459851083, COSV100626028; called by muse, mutect2, varscan2
- EPHA5 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV56684110; called by muse, mutect2, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs756407271; called by mutect2, pindel, varscan2
- EPRS1 | c.3532A>G p.T1178A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100859316, COSV65101719; called by muse, mutect2
- EPRS1 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1170326713, COSV100859317; called by muse, mutect2, varscan2
- EPS8 | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99842670; called by muse, mutect2, varscan2
- EPS8L1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV52384596; called by muse, mutect2, varscan2
- EPX | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756275872, COSV56596516; called by muse, mutect2, varscan2
- ERAP2 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs201095797, COSV65941444; called by muse, mutect2, varscan2
- ERCC6 | c.3643G>A p.A1215T | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs377041857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERCC6L | c.1844C>A p.P615H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559006; called by muse, mutect2, varscan2
- ERG | c.703G>T p.A235S (on ENST00000398919 / NM_001243428.1; = p.A228S on NM_182918.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99901224; called by muse, mutect2, varscan2
- ERN2 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99890598, COSV99892176; called by muse, mutect2, varscan2
- ERN2 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99890600; called by muse, mutect2, varscan2
- ESF1 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.65); catalogued as rs752391066, COSV99176271; called by muse, mutect2, varscan2
- ESF1 | c.512dup p.N171Kfs*24 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs745713173; called by mutect2, varscan2
- ESM1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101195587; called by muse, mutect2, varscan2
- ESX1 | c.176del p.N59Tfs*33 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as COSV65423934; called by mutect2, pindel, varscan2
- ESYT1 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs756912767, COSV99919697; called by muse, mutect2, varscan2
- ESYT3 | c.2598_2600del p.E866del | In Frame Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs1408993818; called by pindel, varscan2
- EVPL | c.5330C>T p.A1777V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1042614433, COSV100044007; called by muse, mutect2, varscan2
- EXOC6 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs966664069, COSV53322698; called by muse, mutect2
- EXOC8 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50477655; called by muse, mutect2, varscan2
- F10 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376163818, CM980650, COSV65023214; called by muse, mutect2, varscan2
- F2 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.376); catalogued as rs142001812; ClinVar: uncertain significance; called by mutect2, varscan2
- F5 | c.2511G>T p.E837D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100888922; called by muse, mutect2, varscan2
- F7 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs767892850, COSV60647798; called by muse, mutect2, varscan2
- F8A1 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100371483; called by mutect2, varscan2
- FAAH2 | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs772777675, COSV66511095; called by mutect2, varscan2
- FADS3 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.033); catalogued as COSV99605134; called by muse, mutect2, varscan2
- FAIM2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100277402; called by muse, mutect2
- FAM111B | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs371411333; called by muse, mutect2, varscan2
- FAM117B | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV100287178; called by muse, mutect2, varscan2
- FAM120A | c.3269C>T p.T1090I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52902950, COSV99464594; called by muse, mutect2, varscan2
- FAM172A | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs1157421441, COSV101232661; called by muse, mutect2, varscan2
- FAM187B | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs1244806617, COSV61201063, COSV61201217; called by muse, mutect2, varscan2
- FAM193A | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs1280568144, COSV100218602; called by muse, mutect2, varscan2
- FAM193A | c.2462G>A p.R821Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61192110; called by muse, mutect2, varscan2
- FAM200A | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV101282703; called by muse, mutect2, varscan2
- FAM47C | c.599del p.P200Rfs*625 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as COSV63726734; called by mutect2, pindel, varscan2
- FAM50B | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100976512; called by muse, mutect2
- FAM53B | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100483937; called by muse, mutect2, varscan2
- FAM83C | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs753833214, COSV65582906, COSV65584304; called by muse, mutect2, varscan2
- FAM98B | c.418T>A p.L140I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.211); catalogued as COSV99989047; called by muse, mutect2, varscan2
- FANCM | c.762T>G p.A254= | Splice Region (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99950494; called by muse, mutect2, varscan2
- FARSA | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775334415, COSV100108664, COSV58904882; called by muse, mutect2, varscan2
- FAT1 | c.4115C>T p.P1372L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101499085; called by muse, mutect2
- FAT1 | c.2431G>A p.V811M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.214); catalogued as rs765982067, COSV101499087; called by muse, mutect2, varscan2
- FAT4 | c.13349G>A p.G4450D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV100627306; called by muse, mutect2, varscan2
- FBLN2 | c.641del p.G214Vfs*60 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs1442883568; called by mutect2, pindel, varscan2
- FBN3 | c.2728G>A p.V910M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs775664860, COSV99559926; called by muse, mutect2, varscan2
- FBXL13 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs142888806; called by muse, mutect2, varscan2
- FBXL17 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs149894091; called by muse, mutect2, varscan2
- FBXL2 | c.887G>A p.C296Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99371648; called by muse, mutect2, varscan2
- FBXL22 | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV100634374; called by muse, mutect2
- FBXL5 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100377662; called by muse, mutect2, varscan2
- FBXL7 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.12); catalogued as COSV100309120; called by muse, mutect2, varscan2
- FBXO10 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV99446280; called by muse, mutect2, varscan2
- FBXO15 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs549233857, COSV54042674; called by muse, mutect2, varscan2
- FBXO28 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100837354; called by muse, mutect2, varscan2
- FBXO32 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV99785833; called by muse, mutect2, varscan2
- FBXO46 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1182434651, COSV100479987; called by muse, mutect2, varscan2
- FBXO7 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs568297516, COSV56678713; called by muse, mutect2, varscan2
- FBXW11 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99439820; called by muse, mutect2, varscan2
- FBXW12 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV99601455; called by muse, mutect2, varscan2
- FCGR2A | c.790C>T p.R264C (on ENST00000271450 / NM_001136219.3; = p.R263C on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs371071000; called by muse, mutect2, varscan2
- FCN1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs371244932; called by muse, mutect2, varscan2
- FCN1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs755837291, COSV100878815; called by muse, mutect2, varscan2
- FCRL2 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs760559249, COSV100829835, COSV63833207; called by muse, mutect2, varscan2
- FCRL5 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100708560; called by muse, mutect2, varscan2
- FGB | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs530036524, COSV100122320, COSV57417909; called by muse, mutect2, varscan2
- FGD5 | c.3328C>T p.P1110S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53250017; called by muse, mutect2, varscan2
- FGF6 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV57405315; called by muse, mutect2, varscan2
- FGFR1 | c.1977C>T p.N659= (on ENST00000447712 / NM_023110.3; = p.N657= on NM_015850.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 13/70 reads (19%) | catalogued as rs1296971200, COSV58342038; called by muse, mutect2, varscan2
- FIBP | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1385548286, COSV100327203; called by muse, mutect2, varscan2
- FIBP | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100327205; called by muse, mutect2, varscan2
- FIS1 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs776529563, COSV56191034; called by muse, mutect2, varscan2
- FLCN | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as rs367843558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.4745C>T p.A1582V | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs996257866, COSV100912221, COSV64252071; called by muse, mutect2, varscan2
- FLNA | c.4157G>A p.G1386D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100774299; called by muse, mutect2, varscan2
- FLNA | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV61043516; called by muse, mutect2, varscan2
- FLVCR2 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV99471062; called by muse, mutect2
- FMN1 | c.2617G>A p.A873T (on ENST00000616417 / NM_001277313.2; = p.A650T on NM_001103184.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.552); catalogued as rs372119445; called by muse, mutect2, varscan2
- FMO3 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs765775795, COSV100882400; called by muse, mutect2, varscan2
- FNDC1 | c.2392G>A p.G798R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs757273488, COSV99794990; called by muse, varscan2
- FOXD4 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs746864855, COSV58698601; called by muse, mutect2, varscan2
- FOXD4L4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1352810874; called by muse, mutect2, varscan2
- FOXN1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs767313142, COSV56883270, COSV99880968; called by muse, mutect2, varscan2
- FOXP1 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.379); catalogued as COSV100561104; called by mutect2, varscan2
- FOXR2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100189407; called by muse, mutect2, varscan2
- FOXRED2 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99340704; called by muse, mutect2, varscan2
- FPR3 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as COSV100200588; called by muse, mutect2, varscan2
- FREM1 | c.4730T>C p.V1577A | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs748026276, COSV101083850; called by muse, mutect2, varscan2
- FRMD4B | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.431); catalogued as rs377577151; called by muse, mutect2, varscan2
- FRMPD3 | c.3159G>A p.W1053* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99345729; called by muse, mutect2, varscan2
- FSD2 | c.1304T>C p.V435A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs760175457, COSV100575017; called by muse, mutect2, varscan2
- FUT5 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760071180, COSV99398545; called by muse, mutect2, varscan2
- FUT8 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.653); catalogued as COSV100651065; called by muse, mutect2, varscan2
- FUZ | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1191647046, COSV100571004; called by muse, mutect2, varscan2
- FUZ | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV100571007; called by muse, mutect2, varscan2
- FXR1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99976124; called by muse, mutect2, varscan2
- FZD10 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361067903, COSV57474313, COSV57475915; called by muse, mutect2, varscan2
- FZD2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59529422; called by muse, mutect2, varscan2
- GAB2 | c.1786G>A p.V596I (on ENST00000361507 / NM_080491.3; = p.V558I on NM_012296.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs145573768; called by muse, mutect2
- GABRA1 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV50115651; called by muse, mutect2, varscan2
- GABRG1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV99777456; called by muse, mutect2, varscan2
- GABRG1 | c.792del p.F264Lfs*3 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs772301203; called by mutect2, varscan2
- GABRR2 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101298854; called by muse, mutect2
- GAL3ST3 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100360718; called by muse, mutect2, varscan2
- GAL3ST3 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1440832456, COSV100360720; called by muse, mutect2, varscan2
- GALNT12 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as rs145557511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT13 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV101222247, COSV67243847; called by muse, mutect2, varscan2
- GALNT17 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100352460; called by muse, mutect2, varscan2
- GAREM1 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs1373703454, COSV99330228; called by muse, mutect2, varscan2
- GAS2L2 | c.2433del p.K812Rfs*5 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as rs782288149; called by mutect2, pindel, varscan2
- GAS7 | c.1316G>A p.S439N (on ENST00000432992 / NM_201433.2; = p.S299N on NM_003644.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs1357662469, COSV100094625; called by muse, mutect2, varscan2
- GATAD2A | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99389666; called by muse, mutect2, varscan2
- GCK | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100357023; called by muse, mutect2, varscan2
- GCLM | c.815G>T p.R272M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.044); catalogued as COSV100933973; called by mutect2, varscan2
- GCN1 | c.6126G>T p.E2042D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100324694; called by muse, mutect2, varscan2
2,464 further variants in this file (1,660 protein-altering or splice-affecting, 731 silent, 73 other) are not listed here.
